Somatic mutation profile of tumor specimen TCGA-69-7760-01A (aliquot TCGA-69-7760-01A-11D-2167-08) from TCGA case TCGA-69-7760, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.3 years (26,777 days).
Specimen TCGA-69-7760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59ee2866-a2d5-4544-804b-005bf4aee445.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7760-10A (Blood Derived Normal), aliquot TCGA-69-7760-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f412cb0d-3502-40eb-aad0-f0ca27986ae0

The open-access MAF lists 76 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Nonsense Mutation 5, RNA 3, Frame Shift Del 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2127_2129del p.E709_T710delinsD | In Frame Del (DEL) | VAF 82/163 reads (50%) | hotspot (GDC flag); catalogued as rs397517086, COSV51779132; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.808T>G p.F270V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.2031G>A p.W677* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV57861785; called by muse, mutect2, varscan2
- AGAP1 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV58319332; called by muse, mutect2, varscan2
- ARAP2 | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV58283632; called by muse, mutect2, varscan2
- ARHGAP6 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs1456016444, COSV57292638; called by muse, mutect2, varscan2
- ATP13A4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as rs148750067; called by muse, mutect2, varscan2
- C1orf35 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54341944; called by muse, mutect2, varscan2
- C9orf131 | c.3014C>A p.P1005H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV56609910; called by muse, mutect2, varscan2
- CCDC15 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61080582; called by muse, mutect2
- CEP126 | c.3345C>A p.D1115E | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV54822401; called by muse, mutect2, varscan2
- CHST4 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV58296653; called by muse, mutect2, varscan2
- CLEC4M | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV50216968; called by muse, mutect2
- DDX25 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373696148; called by muse, mutect2, varscan2
- E2F7 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59737993; called by muse, mutect2
- EAF1 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV67541861; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); catalogued as rs1272049855, COSV62566990; called by muse, mutect2, varscan2
- EIF3I | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV61889810, COSV61890302; called by muse, mutect2, varscan2
- ERICH5 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV59315230; called by muse, mutect2
- FASN | c.5279T>C p.L1760S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60751342; called by muse, mutect2, varscan2
- GATM | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67540217; called by muse, mutect2, varscan2
- GEMIN5 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs779080294, COSV53558730; called by muse, mutect2, varscan2
- IVD | c.584A>G p.N195S (on ENST00000651168; = p.N192S on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV51098810; called by muse, mutect2, varscan2
- LCE2C | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.342); catalogued as rs768416317, COSV64228300; called by muse, mutect2
- MB21D2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765862209, COSV66662658; called by muse, mutect2, varscan2
- MISP | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755955223, COSV53119091; called by muse, mutect2, varscan2
- NUF2 | c.337A>C p.K113Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1370580303, COSV54842474; called by muse, mutect2, varscan2
- OCM | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54194205; called by muse, mutect2
- OR5D16 | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV65721419; called by muse, mutect2, varscan2
- PCDHB2 | c.1516G>T p.V506F | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV50564966; called by muse, mutect2, varscan2
- PGAM2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51977287; called by muse, mutect2, varscan2
- PLEKHG7 | c.1681T>A p.F561I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1261346101, COSV60821247; called by muse, mutect2, varscan2
- POTEE | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100387138; called by muse, varscan2
- RASL10B | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs1302564987; called by mutect2, varscan2
- RYR2 | c.3614G>A p.C1205Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV63668340; called by muse, mutect2
- SEC22A | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV59371250; called by muse, mutect2, varscan2
- SEMA3A | c.1979T>C p.L660P | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54863580; called by muse, mutect2, varscan2
- TAF3 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV100719870; called by muse, mutect2
- TAFA1 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV72037416, COSV72041223; called by muse, mutect2, varscan2
- TMBIM4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1311001607, COSV53968118; called by muse, mutect2
- TMPRSS3 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs763150678, CM154680, COSV52300609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAF5 | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV54821448; called by muse, mutect2, varscan2
- TRIOBP | c.5416C>T p.Q1806* (on ENST00000644935 / NM_001039141.3; = p.Q93* on NM_007032.5) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV58525728; called by muse, varscan2
- TTF1 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs756664211, COSV57502610; called by muse, mutect2, varscan2
- TTN | c.41438T>A p.L13813Q (on ENST00000591111; = p.L6389Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | PolyPhen possibly damaging (0.748); catalogued as COSV59919780; called by muse, mutect2, varscan2
- UBE3B | c.3046C>T p.R1016W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs192805046, COSV61073273; called by muse, mutect2, varscan2
- XRN1 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53808831; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52851718; called by muse, mutect2, varscan2
- ZNF536 | c.3297C>G p.H1099Q | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.157); catalogued as COSV62819936, COSV62827596; called by muse, mutect2, varscan2
- ZNF704 | c.53T>A p.M18K | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs372378549, COSV59920696; called by muse, mutect2, varscan2
- FGD6 | c.3680_3682del p.M1227_C1228delinsS | In Frame Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- SETD2 | c.1619_1620del p.R540Pfs*7 | Frame Shift Del (DEL) | VAF 83/172 reads (48%) | called by mutect2, pindel, varscan2
- TDRD7 | c.170del p.P57Qfs*6 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- TRIOBP | c.5390_5408del p.P1797Lfs*12 (on ENST00000644935 / NM_001039141.3; = p.P84Lfs*12 on NM_007032.5) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by pindel, varscan2
- ADAMTS13 | c.2817T>C p.P939= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV63020246; called by muse, mutect2, varscan2
- ARMC8 | c.294C>T p.V98= (on ENST00000469044 / NM_001363941.2; = p.V84= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV61767820; called by muse, mutect2, varscan2
- CAPRIN2 | c.1728C>T p.S576= | Silent (SNP) | VAF 67/117 reads (57%) | catalogued as rs1340278185, COSV51830823; called by muse, mutect2, varscan2
- CSMD1 | c.2646C>T p.N882= (on ENST00000520002; = p.N881= on NM_033225.6) | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs370427726; called by muse, mutect2, varscan2
- DNAH11 | c.5943A>G p.E1981= | Silent (SNP) | VAF 52/367 reads (14%) | catalogued as COSV60943615; called by muse, mutect2, varscan2
- MB21D2 | c.1212C>T p.R404= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101165030; called by muse, mutect2, varscan2
- NAV1 | c.4296C>T p.I1432= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as COSV55214770; called by muse, mutect2, varscan2
- PCDHB10 | c.312G>T p.L104= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV53376106; called by muse, mutect2, varscan2
- PDAP1 | c.96G>A p.Q32= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV56117036; called by muse, varscan2
- RAD54L2 | c.1663C>T p.L555= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1224156245, COSV56577094; called by muse, mutect2, varscan2
- RFX6 | c.369C>A p.L123= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV60583814; called by muse, mutect2, varscan2
- SEMA5A | c.2409C>T p.G803= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV66786345; called by muse, mutect2, varscan2
- SLC35B2 | c.1170C>A p.V390= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV51488017; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.498C>T p.T166= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs369823894, COSV100602812, COSV59562661; called by muse, mutect2, varscan2
- THSD7A | c.2769T>C p.G923= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV70261228; called by muse, mutect2, varscan2
- TRIM59 | c.1053C>T p.H351= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV59086616; called by muse, mutect2, varscan2
- USP13 | c.1986C>G p.A662= | Silent (SNP) | VAF 15/205 reads (7%) | catalogued as COSV55863251; called by muse, mutect2
- VDAC3 | c.708A>G p.K236= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV50081291; called by muse, mutect2, varscan2
- XPO1 | c.480C>T p.S160= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs772703123, COSV68944912; called by muse, mutect2, varscan2
- OR2W5 | n.1055T>A | RNA (SNP) | VAF 59/189 reads (31%) | called by muse, mutect2, varscan2
- OSGIN1 | n.999G>T | RNA (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100652288; called by muse, mutect2, varscan2
- OSGIN1 | n.1213C>G | RNA (SNP) | VAF 22/130 reads (17%) | catalogued as COSV59419520, COSV59422892; called by muse, mutect2, varscan2
